TCGA case TCGA-06-1084 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ac3582a9-46b1-4322-95fa-9e8b149b8044

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Dead; Days to death: 728 days (2.0 years).

Diagnoses (3)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 54.5 years (19,899 days); Year of diagnosis: 2008; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 16 days; Days to treatment end: 57 days; Treatment dose: 6,000 cGy; Number of fractions: 60; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Days to treatment start: 51 days; Days to treatment end: 51 days; Treatment dose: 1,200 cGy; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 89 days; Days to treatment end: 209 days; Number of cycles: 4; Treatment dose: 500 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 242 days; Days to treatment end: 323 days; Number of cycles: 3; Treatment dose: 1,455 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Initial disease status: Progressive Disease; Days to treatment start: 246 days; Days to treatment end: 288 days; Number of cycles: 2; Treatment dose: 337 mg; Prescribed dose: 125; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 301 days; Days to treatment end: 331 days; Number of cycles: 1; Treatment dose: 180 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 445 days (1.2 years); Days to treatment end: 546 days (1.5 years); Number of cycles: 4; Treatment dose: 81 mg; Prescribed dose: 30; Prescribed dose units: mg/m2; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 55.0 years (20,107 days); Days to diagnosis: 208 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 55.0 years (20,107 days); Days to diagnosis: 208 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (5 entries)
- Day 208 (post initial treatment): Progression or recurrence: Yes; Days to progression: 208 days.
- Days to follow up: 226 days; Disease response: With Tumor.
- Days to follow up: 728 days (2.0 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Preoperative.
- Karnofsky performance status: 70; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-1084-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 0.9; Shortest dimension: 0.5.
  Slide TCGA-06-1084-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent necrosis: 10; Percent stromal cells: 10.
  Slide TCGA-06-1084-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent necrosis: 20; Percent stromal cells: 5.
- Sample TCGA-06-1084-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-1084-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 2, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 03.
- Drug treatment 4: Regimen number: 02.
- Drug treatment 6: Regimen number: 04; Pharmaceutical therapy drug name: Doxil.
- Radiation treatment 1: Radiation type other: Sterotactic radiosurgery.
- Follow-up form 2: Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 728 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 728 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 208 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-1084-01A-01D-0517-01): tumor purity 0.48, ploidy 2.01, whole-genome doublings 0.
